Somatic mutation profile of tumor specimen TCGA-09-2053-01C (aliquot TCGA-09-2053-01C-01W-0722-08) from TCGA case TCGA-09-2053, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.4 years (26,433 days).
Specimen TCGA-09-2053-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a99cf1b3-bb78-411d-b873-86a192f36b2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2053-10A (Blood Derived Normal), aliquot TCGA-09-2053-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a18bbb07-0620-42de-a631-838c09c34031

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 13, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 76/148 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 139/438 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV53990883; called by muse, mutect2, varscan2
- ATP2A2 | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM032192; called by muse, mutect2
- BFAR | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV55493281; called by muse, mutect2, varscan2
- CCDC121 | c.266C>A p.A89E | Missense Mutation (SNP) | VAF 19/506 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99270207, COSV99270539; called by muse, mutect2
- CFAP47 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.955); catalogued as COSV99934577; called by muse, mutect2, varscan2
- CLINT1 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV51624413; called by muse, mutect2, varscan2
- DOCK5 | c.2549A>G p.N850S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV52402576; called by muse, mutect2, varscan2
- FZD5 | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV54943637, COSV54943935; called by muse, mutect2, varscan2
- GPRC5A | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV99185652; called by muse, mutect2
- GTF3C2 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 221/829 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs573699100, COSV53126824; called by muse, mutect2, varscan2
- IGSF6 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV99193641; called by mutect2, varscan2
- IQCJ-SCHIP1 | c.1184G>A p.S395N (on ENST00000485419 / NM_001197113.1; = p.S319N on NM_014575.3) | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV61845919; called by muse, mutect2, varscan2
- ITGB1BP2 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52137802; called by muse, mutect2, varscan2
- KCNS3 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 194/506 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs937664203, COSV58406990; called by muse, mutect2, varscan2
- KRT85 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV57736998; called by muse, mutect2, varscan2
- LRRFIP1 | c.1772T>C p.V591A (on ENST00000392000 / NM_001137552.2; = p.V567A on NM_004735.4) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV55252214; called by muse, mutect2, varscan2
- LRRK2 | c.4714G>A p.A1572T | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54154584; called by muse, mutect2, varscan2
- MDGA1 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 102/487 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs575680310, COSV51798163; called by muse, mutect2, varscan2
- MSR1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 118/402 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs13306549, COSV50508538; called by muse, mutect2, varscan2
- NF1 | c.1649T>C p.L550P | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs886052798, CM1311456, COSV62204901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUDT7 | c.189+1G>T p.X63_splice | Splice Site (SNP) | VAF 67/90 reads (74%) | catalogued as rs926099717, COSV51745507; called by muse, mutect2, varscan2
- ODF2 | c.499C>G p.H167D (on ENST00000434106 / NM_153433.2; = p.H143D on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV63547228; called by muse, mutect2, varscan2
- OR13C5 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV66164659; called by muse, mutect2, varscan2
- OR5L2 | c.203T>C p.F68S | Missense Mutation (SNP) | VAF 191/635 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs201538214; called by muse, mutect2, varscan2
- PAXIP1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765734080, COSV68186404; called by mutect2, varscan2
- PCDHB12 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | catalogued as COSV53394395, COSV99507878; called by muse, mutect2
- PKD1L1 | c.7552G>A p.A2518T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs143415023; called by muse, mutect2, varscan2
- PKN3 | c.1643C>G p.S548C | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV99403378; called by mutect2, varscan2
- PPP1R9A | c.2681G>C p.R894T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV99199077; called by muse, mutect2, varscan2
- PPP2R1A | c.433A>C p.T145P | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV59044834; called by muse, mutect2
- PTPRD | c.5393G>A p.R1798Q | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs367558329, COSV61942413; called by muse, mutect2, varscan2
- RLF | c.237+1G>T p.X79_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV65651964; called by muse, mutect2, varscan2
- RRP15 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.357); catalogued as COSV100860813, COSV65117835; called by muse, mutect2, varscan2
- SCRIB | c.1808T>A p.I603N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV57587449; called by muse, mutect2, varscan2
- SDC2 | c.128T>G p.V43G | Missense Mutation (SNP) | VAF 133/681 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.599); catalogued as rs1382079514, COSV56227767; called by muse, mutect2, varscan2
- SETD5 | c.4107_4108insGA p.S1370Efs*140 | Frame Shift Ins (INS) | VAF 30/264 reads (11%) | catalogued as COSV100201166; called by mutect2, pindel, varscan2
- SI | c.618A>T p.K206N | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV52280241; called by muse, mutect2, varscan2
- SNRNP200 | c.36G>T p.E12D | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100108075; called by muse, mutect2
- STON1-GTF2A1L | c.3527C>G p.A1176G | Missense Mutation (SNP) | VAF 247/1092 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100562313; called by muse, mutect2, varscan2
- SVIL | c.4468G>A p.V1490I (on ENST00000355867 / NM_021738.3; = p.V1064I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as rs148716000; called by muse, mutect2, varscan2
- TEF | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 13/177 reads (7%) | catalogued as COSV99842071; called by muse, mutect2
- TNXB | c.7984G>C p.G2662R (on ENST00000647633; = p.G2415R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768462715, COSV100926407, COSV100926682; called by muse, mutect2, varscan2
- TSKS | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99883733; called by muse, mutect2
- TUBE1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 161/423 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs587773764, COSV100037214; called by muse, mutect2, varscan2
- UTP20 | c.5886C>G p.Y1962* | Nonsense Mutation (SNP) | VAF 19/109 reads (17%) | catalogued as rs747596099, COSV55377907; called by muse, mutect2, varscan2
- UTP6 | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55572601, COSV55576299; called by mutect2, varscan2
- ZNF181 | c.637A>G p.N213D | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV67626773; called by muse, mutect2, varscan2
- ZNFX1 | c.60_61del p.G21Pfs*11 | Frame Shift Del (DEL) | VAF 28/174 reads (16%) | called by pindel, varscan2
- ATL3 | c.63C>T p.S21= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV60296458; called by muse, mutect2, varscan2
- FOXG1 | c.735C>T p.H245= | Silent (SNP) | VAF 48/70 reads (69%) | catalogued as rs1382215123, CD147917, COSV57397011; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSPA1A | c.1737G>A p.S579= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV65149083; called by muse, mutect2, varscan2
- KCNK12 | c.501C>T p.R167= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV59945696; called by muse, mutect2, varscan2
- MAP1A | c.4929G>A p.G1643= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV55809240; called by muse, mutect2, varscan2
- PCDHAC2 | c.1287A>G p.R429= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV53851501; called by muse, mutect2, varscan2
- PRKDC | c.3699G>A p.S1233= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs774629196, COSV58048775; called by muse, mutect2, varscan2
- RBBP8 | c.2494T>C p.L832= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as rs140165933; called by muse, mutect2, varscan2
- RGR | c.309G>A p.A103= | Silent (SNP) | VAF 62/122 reads (51%) | catalogued as rs373030585; called by muse, mutect2, varscan2
- SLC6A18 | c.531C>A p.G177= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as COSV99722698; called by muse, mutect2
- THSD7B | c.1296C>T p.G432= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs754948924, COSV99758504; called by muse, mutect2, varscan2
- TNFRSF21 | c.594G>A p.V198= | Silent (SNP) | VAF 16/382 reads (4%) | catalogued as COSV99730287; called by muse, mutect2
- TRPM3 | c.420T>G p.A140= (on ENST00000357533 / NM_001366142.2; = p.A109= on NM_001007471.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 149/267 reads (56%) | catalogued as COSV62470604; called by muse, mutect2, varscan2
- RPL21 | c.130-150G>T | Intron (SNP) | VAF 41/183 reads (22%) | catalogued as rs1361906526, COSV99699305; called by muse, mutect2, varscan2
